Somatic mutation profile of tumor specimen TCGA-52-7812-01A (aliquot TCGA-52-7812-01A-11D-2122-08) from TCGA case TCGA-52-7812, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 68.1 years (24,887 days).
Specimen TCGA-52-7812-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a002c863-2a7a-4b74-a8e2-7a31457cf5cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-52-7812-10A (Blood Derived Normal), aliquot TCGA-52-7812-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2179c71e-edfd-4ea8-9fbe-a2888ac9bca9

The open-access MAF lists 332 somatic variants for this specimen: 240 protein-altering or splice-affecting, 87 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 87, Nonsense Mutation 16, Frame Shift Del 9, Splice Site 6, RNA 4, In Frame Del 2, Splice Region 2, Frame Shift Ins 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA10 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.014); catalogued as COSV99288033; called by muse, mutect2, varscan2
- ABCA8 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV99285059; called by muse, mutect2
- ABCB1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as COSV99712343; called by muse, mutect2, varscan2
- ABCD2 | c.1869T>A p.F623L | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV100429203; called by muse, mutect2, varscan2
- ABCF2 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV99734123; called by muse, mutect2, varscan2
- ABCG8 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as COSV99699495; called by muse, mutect2, varscan2
- ACKR4 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.437); catalogued as COSV99391677; called by mutect2, varscan2
- ACTR2 | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99573731; called by muse, mutect2, varscan2
- ADAMTS16 | c.2994C>T p.C998= | Splice Region (SNP) | VAF 8/155 reads (5%) | catalogued as COSV99940327; called by muse, mutect2
- ADCY1 | c.1067G>A p.C356Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99811441; called by muse, mutect2, varscan2
- AKAP12 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV99482667; called by muse, mutect2
- ALPK3 | c.4732T>A p.W1578R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99360353; called by muse, mutect2, varscan2
- AMPD1 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62417387; called by muse, mutect2, varscan2
- ANKRD16 | c.314+1G>C p.X105_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99510360; called by muse, mutect2, varscan2
- ANKRD26 | c.4139G>T p.G1380V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV65776840; called by muse, mutect2, varscan2
- ARHGAP24 | c.548T>A p.V183D (on ENST00000395184 / NM_001025616.3; = p.V90D on NM_031305.3) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99981871; called by muse, mutect2, varscan2
- ARHGAP36 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as COSV99357350; called by muse, mutect2, varscan2
- ARHGEF26 | c.1564A>G p.T522A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100726416; called by muse, mutect2, varscan2
- ARVCF | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767223253, COSV54269466, COSV54269627; called by muse, mutect2, varscan2
- ATAD3A | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100186139; called by muse, mutect2, varscan2
- ATP12A | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV99517139; called by muse, mutect2, varscan2
- ATP8A2 | c.1283A>T p.D428V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99680489; called by muse, mutect2, varscan2
- BCAR1 | c.2422G>T p.V808L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV99366125; called by muse, mutect2, varscan2
- C1orf112 | c.1598A>G p.H533R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as rs757166845, COSV99609487; called by muse, mutect2, varscan2
- CACNA1A | c.2399A>T p.E800V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100801392; called by muse, mutect2, varscan2
- CACNA1C | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775536781, COSV59751679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.1072C>A p.Q358K | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs889216782, COSV100754739; called by muse, mutect2, varscan2
- CCDC87 | c.2514G>C p.Q838H | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100039805; called by muse, mutect2, varscan2
- CCIN | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV100631746; called by muse, mutect2, varscan2
- CCNY | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV99590315; called by muse, mutect2
- CCT8L2 | c.587del p.G196Afs*27 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as COSV100743157; called by mutect2, pindel, varscan2
- CD207 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101338523; called by muse, mutect2, varscan2
- CDC45 | c.683G>T p.W228L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99596489; called by muse, mutect2, varscan2
- CDH7 | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100541599; called by muse, mutect2, varscan2
- CDHR5 | c.1052C>A p.P351Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.799); catalogued as COSV100363316; called by muse, mutect2, varscan2
- CEP128 | c.2624A>T p.Q875L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV99823856, COSV99824481; called by muse, mutect2
- CERK | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99348459; called by muse, mutect2, varscan2
- CFAP47 | c.494T>A p.I165N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99934554; called by muse, mutect2, varscan2
- CHD9 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); catalogued as COSV101271952; called by muse, mutect2, varscan2
- CHL1 | c.2384C>A p.P795H (on ENST00000397491 / NM_001253387.1; = p.P811H on NM_006614.4) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99850367; called by muse, mutect2, varscan2
- CILP2 | c.3380G>A p.G1127D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1372423481, COSV52276350, COSV99364403; called by muse, mutect2, varscan2
- CMPK1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | catalogued as COSV100898556; called by muse, mutect2, varscan2
- CNTNAP5 | c.2468C>A p.A823E | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV101443135; called by muse, mutect2, varscan2
- COL9A3 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as COSV100673322; called by muse, mutect2, varscan2
- COPB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99999313; called by muse, mutect2, varscan2
- CRB2 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100749551; called by muse, mutect2, varscan2
- CRYGC | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774558801, COSV99965255; called by muse, mutect2, varscan2
- CTHRC1 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.1); catalogued as COSV100372931; called by muse, mutect2, varscan2
- CUL1 | c.108C>G p.S36R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100296479; called by muse, mutect2, varscan2
- CUX1 | c.261C>A p.D87E (on ENST00000292535 / NM_181552.4; = p.D98E on NM_001913.5) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.995); catalogued as COSV52893161, COSV99470735; called by muse, mutect2, varscan2
- CXCL9 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV53578241; called by muse, mutect2, varscan2
- CYP7B1 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs777627723, COSV100041006, COSV59583221; called by muse, mutect2, varscan2
- DCAF12L1 | c.1348C>A p.L450I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64422418; called by muse, mutect2, varscan2
- DCAF4L2 | c.404T>A p.L135Q | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100150574, COSV100150783; called by muse, mutect2, varscan2
- DCK | c.401+1G>T p.X134_splice | Splice Site (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99709128; called by muse, varscan2
- DCTN1 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100720876; called by muse, mutect2, varscan2
- DDB1 | c.2425C>T p.Q809* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV100074358; called by muse, mutect2, varscan2
- DES | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100900351; called by muse, mutect2, varscan2
- DGKB | c.1991T>C p.I664T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183139577, COSV99337055; called by muse, mutect2, varscan2
- DNAH3 | c.1040T>G p.V347G | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV54503428, COSV99765482; called by muse, mutect2, varscan2
- DOCK7 | c.2716G>T p.G906W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV99223267; called by muse, mutect2, varscan2
- DRD5 | c.1021T>A p.F341I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100431583; called by muse, mutect2, varscan2
- DSG1 | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99935643; called by muse, mutect2, varscan2
- DYNC1H1 | c.5875G>A p.E1959K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794583; called by muse, mutect2, varscan2
- ENOX2 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV100583873; called by muse, mutect2, varscan2
- FAAH | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs1200378479, COSV99679916; called by muse, mutect2
- FAM3B | c.260A>T p.Y87F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100783716; called by muse, mutect2, varscan2
- FAM76B | c.229A>T p.N77Y | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100334606; called by muse, mutect2, varscan2
- FAR1 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100701676, COSV61386646; called by muse, mutect2, varscan2
- FBXO40 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100572977; called by muse, mutect2, varscan2
- FCHSD1 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1417395154, COSV99781214; called by muse, mutect2, varscan2
- FCRLA | c.227C>G p.T76S (on ENST00000367959; = p.T53S on NM_032738.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV99375724; called by muse, mutect2, varscan2
- FLG | c.4058C>T p.P1353L | Missense Mutation (SNP) | VAF 109/625 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.308); catalogued as COSV100910812, COSV64245117; called by muse, mutect2, varscan2
- FRAS1 | c.9862A>C p.T3288P | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53635843, COSV99349010; called by muse, mutect2, varscan2
- FRMPD2 | c.2575C>G p.Q859E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100563584; called by muse, mutect2, varscan2
- GAB1 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV53756926, COSV99528019; called by mutect2, varscan2
- GAD2 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs758427958, COSV52154457, COSV99392699; called by muse, mutect2, varscan2
- GALNT18 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV99923996; called by muse, mutect2, varscan2
- GBE1 | c.1497G>T p.M499I | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101450109; called by muse, mutect2, varscan2
- GLB1L3 | c.1932T>G p.D644E | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101345124; called by muse, mutect2, varscan2
- GPR132 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs757850974, COSV61678126; called by muse, mutect2, varscan2
- GRIN2A | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV58055684; called by muse, mutect2, varscan2
- H4C6 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100897475; called by muse, mutect2, varscan2
- HDAC5 | c.1001T>A p.F334Y | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.068); catalogued as COSV99870351; called by muse, mutect2, varscan2
- HDAC9 | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs779652721, COSV101286516; called by muse, mutect2, varscan2
- HDGFL2 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100012137; called by muse, mutect2, varscan2
- HEMGN | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754723328, COSV99412297; called by muse, mutect2, varscan2
- HK1 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100065666; called by muse, mutect2, varscan2
- HMCN1 | c.946A>G p.T316A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1020285138, COSV99625245; called by muse, mutect2, varscan2
- HRNR | c.8111C>A p.S2704Y | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100913076; called by muse, varscan2
- IBTK | c.1174A>T p.K392* | Nonsense Mutation (SNP) | VAF 43/116 reads (37%) | catalogued as COSV100090166; called by muse, mutect2, varscan2
- IGLV10-54 | c.263del p.G88Efs*6 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV66505038; called by pindel, varscan2
- IL5RA | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs904451337, COSV99842704; called by muse, mutect2, varscan2
- ILF3 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs780504546, COSV99139420; called by muse, mutect2, varscan2
- INSRR | c.3304G>T p.G1102C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947221, COSV63874948; called by muse, mutect2, varscan2
- ITGA10 | c.3115-2A>G p.X1039_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV65198224; called by muse, mutect2, varscan2
- ITGA4 | c.2288G>C p.R763T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.022); catalogued as rs1209894262, COSV101223162, COSV67896866; called by muse, mutect2, varscan2
- KATNIP | c.2732G>T p.R911L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99850113; called by muse, mutect2, varscan2
- KCNIP4 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV100749130; called by muse, mutect2, varscan2
- KIF19 | c.1092C>G p.Y364* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100738977; called by muse, mutect2
- KIF3C | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 34/136 reads (25%) | catalogued as COSV53100226, COSV99267129; called by muse, mutect2, varscan2
- KIF3C | c.1371G>T p.M457I | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99267130; called by muse, mutect2, varscan2
- KIR3DL3 | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99399761; called by muse, mutect2, varscan2
- KRBA2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1416822284, COSV100497610; called by muse, mutect2, varscan2
- KRT75 | c.240C>A p.C80* | Nonsense Mutation (SNP) | VAF 21/121 reads (17%) | catalogued as COSV99359240; called by muse, mutect2, varscan2
- LARP4B | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV100295133; called by muse, mutect2, varscan2
- LARS1 | c.608G>C p.R203P (on ENST00000394434 / NM_020117.11; = p.R176P on NM_016460.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99198499; called by muse, mutect2, varscan2
- LGR6 | c.1834G>T p.G612C (on ENST00000367278 / NM_001017403.1; = p.G560C on NM_021636.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99706269; called by muse, mutect2, varscan2
- LGR6 | c.1835G>T p.G612V (on ENST00000367278 / NM_001017403.1; = p.G560V on NM_021636.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99706272; called by muse, mutect2, varscan2
- LIMS2 | c.328G>T p.A110S (on ENST00000355119 / NM_001161403.3; = p.A134S on NM_017980.4) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV99760444; called by muse, mutect2, varscan2
- LMX1A | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV99671769; called by muse, mutect2, varscan2
- LMX1A | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV99671771; called by muse, mutect2, varscan2
- LRP2 | c.4756G>T p.G1586C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99786884; called by muse, mutect2, varscan2
- LRRC37B | c.2464G>A p.V822I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.213); catalogued as COSV100496073; called by muse, mutect2, varscan2
- LRRIQ3 | c.1200G>T p.L400F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs1368480756, COSV100598527, COSV100599519; called by muse, mutect2, varscan2
- LUZP4 | c.92-1G>T p.X31_splice | Splice Site (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100904838; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MCTP1 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1167528306, COSV56521607; called by muse, mutect2, varscan2
- ME3 | c.186G>T p.G62= | Splice Region (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100042103, COSV60164937; called by muse, mutect2, varscan2
- MED13 | c.4084C>T p.P1362S | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101180813; called by muse, mutect2, varscan2
- MEMO1 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 81/371 reads (22%) | catalogued as COSV99703820; called by muse, mutect2, varscan2
- MFAP5 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV63946547; called by muse, mutect2, varscan2
- MROH9 | c.1714A>T p.R572* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100882709; called by muse, mutect2, varscan2
- MRPL37 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as rs1311892154, COSV99838881; called by muse, mutect2, varscan2
- MTNR1B | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 179/346 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV99924984; called by muse, mutect2, varscan2
- MUC16 | c.9545C>A p.P3182H | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as COSV101198527, COSV67465828; called by muse, mutect2, varscan2
- MUC16 | c.9544C>A p.P3182T | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.139); catalogued as COSV101198528; called by muse, mutect2, varscan2
- MYCBP2 | c.2845C>T p.Q949* (on ENST00000357337; = p.Q987* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100629375, COSV62040246; called by muse, mutect2, varscan2
- MYH2 | c.494T>A p.F165Y | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99819460; called by muse, mutect2, varscan2
- MYH6 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | catalogued as rs777351999, COSV100676348; called by muse, mutect2, varscan2
- MYO7A | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs199607235, COSV68683577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO7B | c.3617G>T p.G1206V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101267930; called by muse, mutect2, varscan2
- MYOM1 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368232161; called by muse, mutect2, varscan2
- MYT1L | c.1877C>G p.T626S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV101219244; called by muse, mutect2, varscan2
- NCL | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV100502264; called by muse, mutect2, varscan2
- NCR1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99400804; called by muse, mutect2, varscan2
- NEK2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV100878531; called by muse, mutect2, varscan2
- NKTR | c.1303A>C p.K435Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV99235320; called by muse, mutect2, varscan2
- OR4P4 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1193734783, COSV100111601, COSV58921907; called by muse, mutect2, varscan2
- OR51B4 | c.783T>A p.F261L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100970803; called by muse, mutect2, varscan2
- OR56B4 | c.688T>C p.S230P | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100337633; called by muse, mutect2, varscan2
- OR9I1 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109496; called by muse, mutect2, varscan2
- PAPPA2 | c.3211C>A p.H1071N | Missense Mutation (SNP) | VAF 117/277 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100867641; called by muse, mutect2, varscan2
- PARP10 | c.1159C>A p.P387T | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100477795; called by muse, mutect2, varscan2
- PARP9 | c.1489+1G>C p.X497_splice | Splice Site (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100830980; called by muse, mutect2, varscan2
- PCDH11X | c.2744C>G p.T915R | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.756); catalogued as COSV100009124; called by muse, mutect2, varscan2
- PCDH15 | c.5185C>A p.P1729T (on ENST00000644397 / NM_001354429.2; = p.P1671T on NM_001142771.2) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100903407, COSV100904782; called by muse, mutect2, varscan2
- PEX5 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99870737; called by muse, mutect2, varscan2
- PGBD4 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.18); catalogued as COSV99854745; called by muse, mutect2, varscan2
- PIK3CG | c.2844C>A p.H948Q | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100782626; called by muse, mutect2
- PIK3CG | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782628; called by muse, mutect2, varscan2
- PIK3R5 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV99352981; called by muse, mutect2, varscan2
- PKD1 | c.8669C>T p.S2890F | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as COSV99237361; called by muse, mutect2, varscan2
- PNMA8A | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV100562274; called by muse, mutect2, varscan2
- POLR2A | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs547350963; called by muse, mutect2, varscan2
- PRAMEF2 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as COSV53575392, COSV53579998; called by muse, mutect2, varscan2
- PRDM2 | c.4748A>G p.K1583R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1263155206, COSV99341048; called by muse, mutect2, varscan2
- PRDM5 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV99310011; called by muse, mutect2, varscan2
- PREX2 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV55776199, COSV55783803; called by muse, mutect2, varscan2
- PTPN12 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99950148; called by muse, mutect2, varscan2
- PTPRH | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV99670779; called by muse, mutect2, varscan2
- RAB5B | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100822086; called by muse, mutect2, varscan2
- RBM10 | c.1176T>A p.N392K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as COSV100237410; called by muse, mutect2
- RGS6 | c.1215C>A p.H405Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100665332; called by muse, mutect2, varscan2
- RIF1 | c.5305G>A p.A1769T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99690192; called by muse, mutect2, varscan2
- RNF125 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99470409; called by muse, mutect2, varscan2
- RP1L1 | c.6105G>T p.Q2035H | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as COSV66761122; called by muse, mutect2, varscan2
- RUNDC3B | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.034); catalogued as rs778997280, COSV100406843; called by muse, mutect2, varscan2
- RYR2 | c.3852G>T p.K1284N | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1445796507, COSV100768568; called by muse, mutect2, varscan2
- SCN1B | c.269del p.V90Gfs*57 | Frame Shift Del (DEL) | VAF 45/180 reads (25%) | catalogued as COSV52894998; called by mutect2, pindel, varscan2
- SDF2L1 | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV99963612; called by muse, mutect2, varscan2
- SEMA6A | c.2359T>A p.C787S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.999); catalogued as COSV99145583; called by muse, mutect2, varscan2
- SF3B1 | c.2893T>A p.C965S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100133977; called by muse, mutect2, varscan2
- SIRPB1 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53537775, COSV99498190; called by muse, mutect2, varscan2
- SLC14A2 | c.1830G>C p.Q610H | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV99675150; called by muse, mutect2, varscan2
- SLC39A12 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.706); catalogued as COSV101069891; called by muse, mutect2, varscan2
- SLC4A7 | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.478); catalogued as COSV99839310; called by muse, mutect2, varscan2
- SLC7A2 | c.1069A>T p.I357F | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV99134427; called by muse, mutect2, varscan2
- SLC8A2 | c.1349C>A p.T450K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV52639879, COSV99369725; called by muse, mutect2, varscan2
- SLCO4C1 | c.287A>T p.Q96L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV100194614; called by muse, mutect2, varscan2
- SLF2 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as rs1470359022, COSV53271816; called by muse, mutect2, varscan2
- SMARCA1 | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100946394, COSV64410627; called by muse, mutect2, varscan2
- SORCS1 | c.3217C>A p.L1073M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99544022; called by muse, mutect2, varscan2
- SOX9 | c.1106A>T p.Q369L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99818226; called by muse, mutect2
- SP140 | c.1051G>T p.G351W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV100613469; called by muse, mutect2, varscan2
- STIL | c.1997G>T p.R666I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.748); catalogued as COSV54549689, COSV99680652; called by muse, mutect2, varscan2
- SULT1B1 | c.368A>T p.N123I | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100150145; called by muse, mutect2, varscan2
- TACC2 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV100551748; called by muse, mutect2, varscan2
- TIAM1 | c.4106C>T p.P1369L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99733309; called by muse, mutect2, varscan2
- TJP1 | c.4424C>T p.P1475L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100632408; called by muse, mutect2, varscan2
- TLE4 | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54631910, COSV54635266; called by muse, mutect2, varscan2
- TLN2 | c.7337A>G p.K2446R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV100168248; called by muse, mutect2, varscan2
- TLX3 | c.318C>A p.S106R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as rs1483934469, COSV99740481; called by muse, mutect2
- TMCO6 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV99347017; called by muse, mutect2, varscan2
- TMEM143 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV99506989; called by muse, mutect2, varscan2
- TP53BP1 | c.4064G>C p.R1355P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV55512234; called by muse, mutect2, varscan2
- TPH1 | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100000690; called by muse, mutect2, varscan2
- TRIM36 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142282; called by muse, mutect2, varscan2
- TRMT112 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99134479; called by muse, mutect2, varscan2
- TRO | c.3439C>A p.L1147I | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.723); catalogued as COSV51503548; called by muse, mutect2, varscan2
- TRPM1 | c.2190G>T p.Q730H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99855482; called by muse, mutect2, varscan2
- TRPM6 | c.596T>A p.L199* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100665647; called by muse, mutect2, varscan2
- TSPY1 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101369644; called by muse, mutect2, varscan2
- TYROBP | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.59); catalogued as COSV99385525; called by muse, mutect2, varscan2
- UNC5A | c.602C>G p.T201R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.089); catalogued as COSV99994265; called by muse, mutect2, varscan2
- USF3 | c.4332T>A p.H1444Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100324836; called by muse, mutect2, varscan2
- USP9Y | c.823T>G p.Y275D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100168226; called by muse, mutect2, varscan2
- VEGFC | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1255751012, COSV99709544; called by muse, mutect2, varscan2
- VRTN | c.2066G>T p.W689L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99832138; called by muse, varscan2
- VWC2L | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as COSV100435363, COSV56971101; called by muse, mutect2, varscan2
- XAB2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100222000; called by muse, mutect2
- XRN2 | c.2357G>T p.W786L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV101018091, COSV65871954; called by muse, mutect2, varscan2
- ZHX2 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58711537; called by muse, mutect2, varscan2
- ZNF226 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763778300, COSV100335034; called by muse, mutect2, varscan2
- ZNF229 | c.1722C>G p.C574W | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99350139; called by muse, mutect2, varscan2
- ZNF251 | c.1151A>T p.K384M | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99478196; called by muse, mutect2, varscan2
- ZNF304 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV99988441; called by muse, mutect2, varscan2
- ZNF358 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99900420; called by muse, mutect2, varscan2
- ZNF433 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs149901945, COSV100794953; called by muse, mutect2, varscan2
- ZNF536 | c.3468C>A p.N1156K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV100834821; called by muse, mutect2, varscan2
- ZNF607 | c.1318A>T p.N440Y | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100777833; called by muse, mutect2, varscan2
- ZNF626 | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV101656951; called by muse, mutect2, varscan2
- ZNF804A | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100166732; called by muse, mutect2, varscan2
- ZYX | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as rs368759415; called by muse, mutect2
- AC242842.3 | c.433del p.Q145Kfs*173 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, varscan2
- AC242842.3 | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- AKAP11 | c.3448_3451del p.S1150Rfs*7 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- COL7A1 | c.3957dup p.G1320Wfs*40 | Frame Shift Ins (INS) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- DDX39A | c.958del p.M320Wfs*66 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- GZF1 | c.1153_1155del p.K385del | In Frame Del (DEL) | VAF 20/91 reads (22%) | called by pindel, varscan2
- MDGA2 | c.2822_2823del p.G941Efs*2 (on ENST00000399232 / NM_001113498.2; = p.G643Efs*2 on NM_182830.4) | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- MORC4 | c.2286del p.K762Nfs*2 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- NUP210 | c.2622_2628+3del p.X874_splice | Splice Site (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- PROX1 | c.1449del p.F484Sfs*5 | Frame Shift Del (DEL) | VAF 30/147 reads (20%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.2230C>A p.L744I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.181); called by muse, mutect2
- TRBV5-1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- VN1R5 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- VPS54 | c.1078_1086del p.T360_S362del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- ABCG8 | c.588G>T p.R196= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs952029008, COSV99699496; called by muse, mutect2, varscan2
- ADAM19 | c.2017C>T p.L673= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99976344; called by muse, mutect2, varscan2
- ADAMTS13 | c.3942G>A p.S1314= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs782408438, COSV52471121; called by muse, mutect2, varscan2
- AOC1 | c.33C>T p.I11= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs377703686; called by muse, mutect2, varscan2
- ARHGEF9 | c.675C>T p.R225= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99491446; called by muse, mutect2
- ASB16 | c.1320C>T p.L440= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs768294868, COSV99518778; called by muse, mutect2, varscan2
- ATP8B3 | c.1836C>G p.S612= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs369853245, COSV100034130; called by muse, mutect2, varscan2
- BDP1 | c.5811A>T p.I1937= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100702808; called by muse, mutect2, varscan2
- CD82 | c.489G>A p.E163= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV99907414; called by muse, mutect2, varscan2
- CETN1 | c.453G>T p.R151= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100511236, COSV59121504; called by muse, mutect2, varscan2
- CNGA1 | c.228G>A p.E76= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100652154; called by muse, mutect2, varscan2
- COCH | c.993C>A p.I331= (on ENST00000216361 / NM_001347720.1; = p.I266= on NM_004086.3) | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV53550811, COSV99363433; called by muse, mutect2, varscan2
- COL9A3 | c.1251A>T p.P417= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100673321; called by muse, mutect2, varscan2
- CTCFL | c.1953C>A p.G651= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV54771084, COSV99712237; called by muse, mutect2, varscan2
- DCAF4L2 | c.1179C>A p.S393= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV60476450; called by muse, mutect2, varscan2
- DCLK1 | c.1014A>T p.P338= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99709547; called by muse, mutect2, varscan2
- DHX32 | c.1140C>T p.I380= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV99501431; called by muse, mutect2
- DPP6 | c.1080C>A p.G360= (on ENST00000377770 / NM_001364500.2; = p.G298= on NM_001936.5) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100123587; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.462A>T p.S154= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV99143596; called by muse, mutect2, varscan2
- DYNC1H1 | c.13164G>T p.L4388= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100794584; called by muse, mutect2, varscan2
- EIF4G3 | c.2319G>A p.L773= | Silent (SNP) | VAF 73/220 reads (33%) | catalogued as COSV99943482; called by muse, mutect2, varscan2
- FGFRL1 | c.537G>C p.R179= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99294488; called by muse, varscan2
- FRMD7 | c.684C>T p.I228= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100048736; called by muse, mutect2, varscan2
- GABRR2 | c.519G>C p.T173= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101298867; called by muse, varscan2
- GLI2 | c.3468G>T p.V1156= (on ENST00000361492 / NM_001374353.1; = p.V1173= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs764853095, COSV100082555; called by muse, mutect2, varscan2
- GOLPH3 | c.541C>T p.L181= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1264622862, COSV99417047; called by muse, mutect2, varscan2
- GRK3 | c.1881G>A p.G627= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100151215; called by muse, mutect2, varscan2
- HACD4 | c.300G>A p.V100= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV101529950; called by muse, mutect2, varscan2
- HUS1 | c.783G>A p.V261= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1282520296, COSV99346409; called by muse, mutect2
- IGHV2-70 | c.195C>A p.A65= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- IMPDH2 | c.72C>T p.F24= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs769173346, COSV100454958; called by muse, varscan2
- ITLN1 | c.771C>A p.T257= | Silent (SNP) | VAF 68/188 reads (36%) | catalogued as COSV100406138; called by muse, mutect2, varscan2
- ITPRIP | c.1434C>T p.F478= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV53392741, COSV99532434; called by muse, mutect2, varscan2
- KCNA6 | c.396G>T p.A132= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV54975056, COSV99768404; called by muse, mutect2, varscan2
- KRT74 | c.444C>T p.N148= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as rs267607205, CM102151, COSV99977411; called by muse, mutect2, varscan2
- LCT | c.3556C>T p.L1186= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV99928780; called by muse, mutect2, varscan2
- MARCHF4 | c.555C>A p.V185= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99814128; called by muse, mutect2, varscan2
- MUC16 | c.11199G>C p.L3733= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV101198526, COSV67476816; called by muse, mutect2
- MYBPC2 | c.1227A>T p.S409= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100731650; called by muse, mutect2, varscan2
- MYO18B | c.4494C>A p.A1498= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- NAV3 | c.300C>A p.I100= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV57116564, COSV99887745; called by muse, mutect2, varscan2
- NEIL2 | c.726G>C p.G242= | Silent (SNP) | VAF 81/228 reads (36%) | catalogued as COSV99462143; called by muse, mutect2, varscan2
- NLRP7 | c.2277T>C p.H759= (on ENST00000340844 / NM_206828.3; = p.H731= on NM_139176.3) | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100051799; called by muse, mutect2, varscan2
- NUDT14 | c.129G>T p.V43= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100241974, COSV100241979; called by muse, mutect2, varscan2
- OR2A5 | c.636C>T p.C212= | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as COSV101278678; called by muse, mutect2, varscan2
- OR2W3 | c.343C>T p.L115= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100831617; called by muse, mutect2, varscan2
- OR5H1 | c.828A>T p.L276= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as rs751264873, COSV100641635, COSV63402303; called by muse, mutect2, varscan2
- OR5H15 | c.429G>T p.R143= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV62948332; called by muse, mutect2, varscan2
- OR9G4 | c.369T>C p.H123= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as COSV100265033; called by muse, mutect2, varscan2
- P4HTM | c.1140A>G p.A380= (on ENST00000383729 / NM_177939.3; = p.A441= on NM_177938.2) | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs774058003, COSV100637516; called by muse, mutect2, varscan2
- PANK4 | c.234C>T p.P78= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as rs967029743, COSV101022298; called by muse, mutect2, varscan2
- PAQR8 | c.882C>T p.L294= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100658394; called by muse, mutect2, varscan2
- PCBP4 | c.150G>C p.R50= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100436928; called by muse, mutect2, varscan2
- PCDHGA3 | c.1659G>T p.L553= | Silent (SNP) | VAF 53/191 reads (28%) | catalogued as COSV53949699, COSV99532740; called by muse, mutect2, varscan2
- PGR | c.1020C>A p.A340= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV99677599; called by muse, mutect2, varscan2
- POM121C | c.1695C>T p.S565= (on ENST00000607367; = p.S323= on NM_001099415.3) | Silent (SNP) | VAF 88/334 reads (26%) | catalogued as COSV57547329; called by muse, mutect2, varscan2
- POSTN | c.1020A>T p.V340= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV101123266; called by muse, mutect2, varscan2
- PSAP | c.519C>T p.A173= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV101206436; called by muse, mutect2, varscan2
- PTPRD | c.1578T>A p.P526= | Silent (SNP) | VAF 82/153 reads (54%) | catalogued as COSV100643770; called by muse, mutect2, varscan2
- RBP3 | c.1044C>A p.P348= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- RHOU | c.291G>A p.V97= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV64209378; called by muse, mutect2, varscan2
- RIMS2 | c.258G>A p.K86= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV101344252; called by muse, mutect2, varscan2
- ROCK2 | c.1752C>G p.T584= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs1211836382, COSV99837107; called by muse, mutect2, varscan2
- SEMA4F | c.1863G>T p.G621= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV100335789; called by muse, mutect2, varscan2
- SIN3A | c.696C>T p.A232= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100845059; called by muse, mutect2, varscan2
- SLITRK3 | c.2262C>G p.P754= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV53849687, COSV99578690; called by muse, mutect2, varscan2
- SLITRK5 | c.1824G>T p.S608= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs768554234, COSV100280419, COSV61527230; called by muse, mutect2, varscan2
- SRP72 | c.1449C>G p.T483= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100714254; called by muse, mutect2, varscan2
- STK11IP | c.1785G>A p.Q595= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99822403; called by muse, mutect2, varscan2
- STPG2 | c.1302A>T p.P434= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99758290; called by muse, mutect2, varscan2
- STYXL2 | c.1419G>T p.S473= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV54806044; called by muse, mutect2, varscan2
- SUSD1 | c.2154G>A p.S718= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs763208586, COSV62584481; called by muse, mutect2, varscan2
- SVEP1 | c.2718T>C p.S906= | Silent (SNP) | VAF 55/232 reads (24%) | catalogued as COSV100237446; called by muse, mutect2, varscan2
- SVOPL | c.837G>T p.R279= (on ENST00000419765; = p.R127= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV99939098; called by muse, mutect2, varscan2
- TLN1 | c.840C>T p.F280= | Silent (SNP) | VAF 90/155 reads (58%) | catalogued as rs777906241, COSV100147405; called by muse, mutect2, varscan2
- TRIM15 | c.351G>C p.G117= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100938786, COSV64990280; called by muse, mutect2, varscan2
- TRPM6 | c.3408C>G p.L1136= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100665643; called by muse, mutect2, varscan2
- TRPV4 | c.709C>A p.R237= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as CM160666, COSV55681778, COSV99924446; called by muse, mutect2, varscan2
- TTK | c.2437C>T p.L813= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100036058, COSV57882084; called by muse, mutect2, varscan2
- VPS52 | c.1059C>G p.V353= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV101460413; called by muse, mutect2, varscan2
- WDR43 | c.588G>A p.E196= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99942920; called by muse, mutect2, varscan2
- XIRP2 | c.9955C>T p.L3319= (on ENST00000628543; = p.L3494= on NM_152381.6) | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV99739425; called by muse, mutect2, varscan2
- ZKSCAN7 | c.204G>T p.P68= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs140731391, COSV99837468; called by muse, mutect2, varscan2
- ZNF423 | c.1879C>A p.R627= (on ENST00000563137 / NM_001379286.1; = p.R619= on NM_015069.4) | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV99280309; called by muse, mutect2, varscan2
- ZNF831 | c.3405T>A p.T1135= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100925845; called by muse, mutect2, varscan2
- ZNFX1 | c.3435G>A p.L1145= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as rs1227579690, COSV100872208; called by muse, mutect2, varscan2
- ZRANB3 | c.1513T>C p.L505= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99922803; called by muse, mutect2, varscan2
- DCHS2 | n.2973G>T | RNA (SNP) | VAF 33/102 reads (32%) | catalogued as rs1276621919, COSV100251092, COSV59737657; called by muse, mutect2, varscan2
- FOLH1B | n.956G>T | RNA (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- MROH1 | c.1142-7485T>A | Intron (SNP) | VAF 66/189 reads (35%) | catalogued as COSV100395618; called by muse, mutect2, varscan2
- OR2W5 | n.374G>A | RNA (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- OR2W5 | n.1054C>A | RNA (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
